Somatic mutation profile of tumor specimen BA2970D (aliquot aq-BA2970D) from BEATAML1.0 case 2327, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.3 years (23,120 days).
Specimen BA2970D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 35c08b4c-dfdf-44d8-995d-34c96dd90691.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2362D (Solid Tissue Normal), aliquot aq-BA2362D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c5b5f69-1d59-4980-be85-066243462d40

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 2, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIFC2 | c.782G>A p.G261D | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); catalogued as rs765546348; called by muse, varscan2
- CAMK2A | c.1208G>T p.W403L (on ENST00000348628 / NM_171825.2; = p.W414L on NM_015981.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM88 | c.461C>A p.S154* | Nonsense Mutation (SNP) | VAF 3/16 reads (19%) | called by muse, mutect2
- USP32 | c.186G>T p.E62D | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.1); called by muse, mutect2
- CNOT6L | c.180G>T p.A60= (on ENST00000504123 / NM_001286790.2; = p.A55= on NM_144571.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/97 reads (5%) | called by muse, mutect2
- MARS2 | c.1134C>A p.G378= | Silent (SNP) | VAF 6/100 reads (6%) | called by muse, mutect2
- CCDC188 | c.733-19T>C | Intron (SNP) | VAF 6/14 reads (43%) | catalogued as rs73150876; called by muse, varscan2
